Somatic mutation profile of tumor specimen ALCH-B268-TTP1-A (aliquot ALCH-B268-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B268, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.4 years (21,681 days).
Specimen ALCH-B268-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f191cf40-7fb3-4e14-bd58-25755dbf8c48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B268-NB1-A (Blood Derived Normal), aliquot ALCH-B268-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1143151-c862-45cc-aeda-e92f547dd727

The open-access MAF lists 60 somatic variants for this specimen: 44 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 11, Nonsense Mutation 4, Intron 2, Frame Shift Del 1, 5'UTR 1, 3'Flank 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 18/134 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRB1 | c.4377C>A p.N1459K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs765210709; called by muse, mutect2, varscan2
- CCAR1 | c.2648A>G p.D883G | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs1289816723; called by muse, varscan2
- H1-3 | c.556G>C p.A186P | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs752873353; called by muse, mutect2, varscan2
- IFI44 | c.1106G>A p.R369K | Missense Mutation (SNP) | VAF 42/409 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748628209, COSV104425790; called by muse, varscan2
- KCNQ5 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 37/276 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs781763407, COSV59658177; called by muse, mutect2, varscan2
- NAV3 | c.3278T>C p.L1093P | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1453420014; called by muse, mutect2, varscan2
- NKX6-1 | c.817T>A p.L273M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99879948; called by muse, mutect2, varscan2
- OR12D2 | c.266C>A p.A89E | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs368405941; called by muse, mutect2, varscan2
- SYNE1 | c.25153G>C p.D8385H (on ENST00000367255 / NM_182961.4; = p.D8337H on NM_033071.3) | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55045415; called by muse, mutect2
- ZFP69B | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as rs1300309232; called by muse, mutect2, varscan2
- ZFPM2 | c.984C>A p.F328L | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV65874556, COSV65876569; called by muse, mutect2
- ZNF354A | c.1708A>G p.R570G | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1240699226; called by muse, varscan2
- ATP6V0D2 | c.196A>G p.T66A | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CDIN1 | c.146A>G p.Q49R | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CNTN1 | c.486C>A p.Y162* | Nonsense Mutation (SNP) | VAF 34/470 reads (7%) | called by muse, mutect2
- CNTN1 | c.487C>G p.H163D | Missense Mutation (SNP) | VAF 36/474 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CRELD1 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
- DACH2 | c.1260T>G p.I420M | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.293); called by muse, mutect2
- DNAJC13 | c.91G>T p.G31* | Nonsense Mutation (SNP) | VAF 26/265 reads (10%) | called by muse, mutect2, varscan2
- EDARADD | c.645C>A p.F215L (on ENST00000334232 / NM_145861.4; = p.F205L on NM_080738.4) | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2
- ERO1A | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 15/147 reads (10%) | called by muse, mutect2, varscan2
- FSIP2 | c.12844G>T p.V4282F | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- HMCN1 | c.9707A>G p.Y3236C | Missense Mutation (SNP) | VAF 49/348 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- HOOK3 | c.1481G>C p.S494T | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KCNH5 | c.1606A>C p.I536L | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MTIF2 | c.1529A>T p.E510V | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.069); called by muse, mutect2
- NEFL | c.1475C>A p.A492D | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10G2 | c.95T>G p.F32C | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2
- OR4K5 | c.854T>C p.I285T | Missense Mutation (SNP) | VAF 28/442 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2
- PDE6C | c.2191T>C p.W731R | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIK3R6 | c.244T>C p.Y82H | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- RABGEF1 | c.1379G>T p.R460I (on ENST00000439720 / NM_001287061.2; = p.R447I on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SAR1B | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 58/365 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA6D | c.1949T>A p.V650D (on ENST00000316364 / NM_153618.2; = p.V588D on NM_020858.2) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.649); called by muse, varscan2
- SLC6A12 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2
- SPANXN2 | c.407A>T p.Q136L | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, varscan2
- SRP54 | c.287C>A p.P96H | Missense Mutation (SNP) | VAF 24/283 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- ST6GALNAC5 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | PolyPhen benign (0.081); called by muse, varscan2
- TPTE | c.1170+1G>A p.X390_splice (on ENST00000618007 / NM_199261.4; = p.X372_splice on NM_199259.4) | Splice Site (SNP) | VAF 24/284 reads (8%) | called by muse, mutect2
- TSC22D3 | c.154A>G p.N52D | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- VAV3 | c.1764del p.K588Nfs*41 | Frame Shift Del (DEL) | VAF 24/162 reads (15%) | called by mutect2, pindel, varscan2
- ZNF396 | c.497A>G p.Q166R | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- ZP4 | c.1348G>T p.A450S | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.041); called by muse, mutect2
- CMYA5 | c.6075C>T p.N2025= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs1431542810, COSV71404341, COSV71408880; called by muse, mutect2, varscan2
- CREB3L3 | c.492G>A p.E164= | Silent (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- EBF1 | c.1632A>T p.S544= | Silent (SNP) | VAF 13/140 reads (9%) | called by muse, mutect2
- MON1A | c.1182C>T p.P394= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- MUC4 | c.12102T>G p.P4034= | Silent (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- NEUROD6 | c.409C>A p.R137= | Silent (SNP) | VAF 35/237 reads (15%) | catalogued as COSV51770486; called by muse, mutect2, varscan2
- OR10G2 | c.93C>A p.L31= | Silent (SNP) | VAF 13/117 reads (11%) | catalogued as COSV73390313; called by muse, mutect2
- PLET1 | c.177C>T p.V59= | Silent (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- RFFL | c.723G>A p.L241= | Silent (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2, varscan2
- SLC17A9 | c.1080C>T p.I360= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs1293282138; called by muse, varscan2
- ST6GALNAC5 | c.219A>T p.G73= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, varscan2
- AP000769.3 | chr11:65501546 del AG | 5'Flank (DEL) | VAF 16/136 reads (12%) | catalogued as rs1465664101; called by pindel, varscan2
- IGDCC4 | c.998-152G>T | Intron (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2, varscan2
- PYM1 | c.38-10886G>T | Intron (SNP) | VAF 23/212 reads (11%) | called by muse, mutect2, varscan2
- RPS20 | chr8:56069815 C>A | 3'Flank (SNP) | VAF 20/314 reads (6%) | called by muse, mutect2
- TMEM243 | c.-2A>G | 5'UTR (SNP) | VAF 12/66 reads (18%) | called by mutect2, varscan2
